Somatic mutation profile of tumor specimen BA2020D (aliquot aq-BA2020D) from BEATAML1.0 case 2065, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.7 years (18,874 days).
Specimen BA2020D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25bd093f-6177-4465-a44b-3c7020df6c2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2250D (Solid Tissue Normal), aliquot aq-BA2250D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfecda8e-e5ff-4552-b7d0-ae637b00b158

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DMBT1 | c.6289C>T p.R2097* (on ENST00000338354 / NM_001377530.1; = p.R1340* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as rs1265509713, COSV57543681; called by muse, mutect2, varscan2
- PLEKHG7 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs925886131; called by muse, mutect2, varscan2
- POLI | c.1499G>C p.R500T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as COSV54187511; called by muse, mutect2, varscan2
- RIF1 | c.2678T>C p.I893T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs759227057; called by muse, mutect2, varscan2
- RP1L1 | c.6885A>T p.Q2295H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs1195443052; called by muse, mutect2, varscan2
- ANKRD34C | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ASPH | c.1648G>T p.G550W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGAT2 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.04); called by muse, mutect2
- WWP1 | c.2256C>A p.N752K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ATG2A | c.912G>T p.V304= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- FAM83E | c.534G>A p.T178= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs780481163; called by muse, mutect2, varscan2
- RTN2 | c.1365C>T p.L455= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs776243439, COSV55593446; called by muse, mutect2, varscan2
- STAM | c.-62C>T | 5'UTR (SNP) | VAF 8/27 reads (30%) | catalogued as rs1554820484; called by muse, mutect2, varscan2
